Gene-level copy-number profile of tumor specimen MP2PRT-PASBZW-TTR1-A from MP2PRT case MP2PRT-PASBZW, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 8.0 years (2,921 days).
Specimen MP2PRT-PASBZW-TTR1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 412d2193-6ca3-4fbf-a8b8-718fb92d9acf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASBZW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/bbae7f5e-511d-4c9c-8e11-56e26412cadb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,878; copy number 2: 43,700; copy number 3: 9,577; copy number 4: 2,152; copy number 5: 59; copy number 6: 6.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,157,443, 4 genes: AC116562.1, OR7E103P, UNC93B4, OR7E99P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 65 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:178,094,104–178,484,147, 1 gene, copy number 5 (within-gene range 3–5): RASAL2.
- chr1:178,411,616–179,877,803, 40 genes, copy number 5: AL365357.1, CLEC20A, Metazoa_SRP, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63, ANGPTL1, FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54, AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2, TDRD5, AL359853.2, FAM163A, AL359853.1, LINC02818, TOR1AIP2.
- chr1:182,899,865–182,982,318, 6 genes, copy number 6: SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P.
- chr1:183,929,854–185,102,603, 18 genes, copy number 5: COLGALT2, TSEN15, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25.

Autosomal genes at a single copy (total copy number 1): 2,878. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
